Gene-level copy-number profile of tumor specimen TCGA-VR-A8EQ-01A from TCGA case TCGA-VR-A8EQ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 73.7 years (26,912 days).
Specimen TCGA-VR-A8EQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.9aae706e-d684-4e8f-898e-db0a9ef87697.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VR-A8EQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9ba20efd-9f86-4e1e-a140-f8cf1395aed2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 15,597; copy number 2: 26,940; copy number 3: 14,091; copy number 4: 2,725; copy number 5: 226; copy number 6: 68; copy number 8: 26; copy number 9: 13; copy number 15: 57; copy number 17: 56.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VR-A8EQ-01A-11D-A36I-01): tumor purity 0.35, ploidy 3.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr9:9,090,898–9,803,784, 3 genes (within-gene range 0–1): RPS26P3, RN7SL5P, AL513422.1.
- chr16:78,495,926–78,796,362, 5 genes: AC046158.1, AC046158.4, AC046158.2, AC046158.3, AC009141.1.
- chr20:14,884,250–15,022,958, 4 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 446 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:28,812,142–31,987,034, 68 genes, copy number 6 (broad region; genes not listed).
- chr3:163,026,396–174,378,005, 144 genes, copy number 5 (broad region; genes not listed).
- chr3:174,631,823–175,060,031, 2 genes, copy number 5: RN7SKP40, EEF1B2P8.
- chr18:12,785,478–13,726,663, 26 genes, copy number 8 (within-gene range 1–8): PTPN2, STK25P1, EIF4A2P1, SEH1L, AP002449.1, CEP192, AP001357.2, AP001357.1, AP001198.2, AP001198.1, LDLRAD4, AP002505.1, C18orf15, AP002505.3, AP002505.2, AP002439.1, LDLRAD4-AS1, MIR5190, AP005131.5, AP005131.4, AP005131.2, AP005131.1, AP005131.3, MIR4526, AP001010.1, FAM210A.
- chr18:21,529,284–24,397,880, 69 genes, copy number 9–17 (broad region; genes not listed).
- chr18:26,170,726–27,795,637, 31 genes, copy number 5: DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1.
- chr18:29,256,817–32,774,413, 61 genes, copy number 5–15 (within-gene range 1–15) (broad region; genes not listed).
- chr20:35,615,829–36,951,843, 44 genes, copy number 5: SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39, RPF2P1, U6, PHF20, COX7BP2, Y_RNA, HIGD1AP16, RNU4-40P, RNU6-937P, SCAND1, CNBD2, NORAD, AL035420.1, AL035420.3, HMGB3P2, AL035420.2, EPB41L1, AL121895.1, AL121895.2, AAR2, DLGAP4, DLGAP4-AS1, MYL9, Metazoa_SRP, TGIF2, TGIF2-RAB5IF, RAB5IF, SLA2, HNRNPA3P2, NDRG3, Y_RNA, DSN1, SOGA1, RN7SL156P, TLDC2, SAMHD1.
- chr20:37,021,743–37,021,984, 1 gene, copy number 5: RPS3AP3.

Autosomal genes at a single copy (total copy number 1): 13,214. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
